Somatic mutation profile of tumor specimen TCGA-NC-A5HJ-01A (aliquot TCGA-NC-A5HJ-01A-11D-A26M-08) from TCGA case TCGA-NC-A5HJ, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 59.5 years (21,730 days).
Specimen TCGA-NC-A5HJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b42abbc3-ba6b-4ac1-9a9d-dc0d8505d391.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NC-A5HJ-10A (Blood Derived Normal), aliquot TCGA-NC-A5HJ-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/252c06e6-3910-45a1-8f1f-02eb9498584c

The open-access MAF lists 401 somatic variants for this specimen: 313 protein-altering or splice-affecting, 80 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 283, Silent 80, Nonsense Mutation 10, Splice Site 7, Frame Shift Del 5, Splice Region 4, RNA 4, Intron 2, Frame Shift Ins 2, Nonstop Mutation 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2466T>G p.N822K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913514, COSV55387147, COSV55389584, COSV55431266; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.216del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 22/158 reads (14%) | catalogued as rs730882018; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2*
- ABCA4 | c.2069G>T p.G690V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD140530, CM042262, CM1210008, COSV100933271; called by muse, mutect2
- ABCB10 | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV100748075; called by muse, mutect2, varscan2
- ABCC12 | c.3802G>T p.A1268S | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100253311; called by muse, mutect2
- ABL2 | c.220G>C p.E74Q (on ENST00000502732 / NM_007314.4; = p.E59Q on NM_005158.5) | Missense Mutation (SNP) | VAF 28/379 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV100773079; called by muse, mutect2
- ACTN3 | c.2155C>A p.H719N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as COSV100074507, COSV100074510; called by muse, mutect2, varscan2
- ADAMTS15 | c.1434G>A p.M478I | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100143802; called by muse, mutect2
- AHNAK2 | c.9892G>T p.D3298Y | Missense Mutation (SNP) | VAF 15/263 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100319038, COSV60909301; called by muse, mutect2
- AICDA | c.389A>C p.H130P | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.113); catalogued as CM1511838, COSV99984376; called by muse, mutect2, varscan2
- AKAP12 | c.1429A>T p.T477S | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV99484484; called by muse, mutect2, varscan2
- AKAP13 | c.642G>T p.K214N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV100774738; called by muse, mutect2, varscan2
- AMBP | c.723G>T p.M241I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV99469396; called by muse, mutect2, varscan2
- AMER3 | c.729C>A p.S243R | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100366935, COSV58465341; called by muse, mutect2, varscan2
- ANKRD45 | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100322686; called by muse, mutect2
- ANKRD50 | c.2530G>A p.D844N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101539055; called by muse, mutect2, varscan2
- AP5M1 | c.1251G>T p.Q417H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV99841378; called by muse, mutect2, varscan2
- APOB | c.5774G>T p.G1925V | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99268267; called by muse, mutect2
- APPBP2 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs200984674; called by muse, mutect2, varscan2
- AQP3 | c.492+2T>C p.X164_splice | Splice Site (SNP) | VAF 18/281 reads (6%) | catalogued as COSV99955709; called by muse, mutect2
- ARHGEF1 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs782100845, COSV61529571; called by muse, mutect2
- ARHGEF15 | c.2098G>T p.D700Y | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100730177; called by muse, mutect2, varscan2
- ARMC4 | c.2244T>A p.N748K | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100537451; called by muse, mutect2, varscan2
- ATN1 | c.1981T>G p.S661A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.396); catalogued as COSV100755968; called by muse, mutect2, varscan2
- ATP10A | c.2345-1G>T p.X782_splice | Splice Site (SNP) | VAF 4/57 reads (7%) | catalogued as COSV100791560; called by muse, mutect2
- ATXN1 | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as COSV99785624, COSV99787930; called by muse, mutect2, varscan2
- ATXN2L | c.1765T>A p.S589T | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as COSV100295245; called by muse, mutect2
- B3GALT1 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100002914; called by muse, mutect2, varscan2
- B3GNT2 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 66/370 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV57344234; called by muse, mutect2, varscan2
- BIRC6 | c.1616G>T p.G539V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (1); catalogued as COSV101428980; called by muse, mutect2, varscan2
- BRWD3 | c.2238G>T p.Q746H | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.94); catalogued as COSV100956573; called by muse, mutect2
- BTN3A1 | c.50G>T p.C17F | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99176255; called by muse, mutect2, varscan2
- BTRC | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.745); catalogued as COSV100926629; called by muse, mutect2
- C1orf174 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.013); catalogued as rs140673232; called by mutect2, varscan2
- C3 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV99837298; called by muse, mutect2
- CA9 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV100999910; called by muse, mutect2
- CAMK4 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV56675295, COSV56680559; called by muse, mutect2
- CCDC54 | c.761T>C p.V254A | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV99660335; called by muse, mutect2, varscan2
- CCT8L2 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV100743157; called by muse, mutect2
- CD109 | c.2453T>A p.V818D | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV99754696; called by muse, mutect2, varscan2
- CD96 | c.1612C>A p.L538I (on ENST00000283285 / NM_198196.3; = p.L522I on NM_005816.5) | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV51916140, COSV99343628; called by muse, mutect2
- CDH5 | c.1188G>T p.M396I | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100439466; called by muse, mutect2, varscan2
- CDH9 | c.2053G>C p.D685H | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.695); catalogued as COSV50273979, COSV99157206; called by muse, mutect2
- CELA1 | c.679G>T p.V227L | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.482); catalogued as COSV99530301; called by muse, mutect2
- CELSR1 | c.3790G>A p.A1264T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99420142; called by muse, mutect2, varscan2
- CFAP69 | c.1345G>T p.A449S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV100290489; called by muse, mutect2, varscan2
- CFH | c.3223T>A p.Y1075N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100810253; called by muse, mutect2
- CGN | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.492); catalogued as COSV99642866; called by muse, mutect2
- CHML | c.652A>T p.T218S | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.078); catalogued as COSV100087902; called by muse, mutect2
- CHRDL1 | c.1131G>A p.K377= (on ENST00000372045; = p.K383= on NM_145234.4) | Splice Region (SNP) | VAF 6/36 reads (17%) | catalogued as COSV54323758, COSV54328409, COSV99488737; called by muse, mutect2
- CNTNAP2 | c.280C>A p.Q94K | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs1294234578, COSV100673042; called by muse, mutect2, varscan2
- CNTNAP5 | c.3818A>T p.Q1273L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV101444260; called by muse, mutect2
- COL1A1 | c.4266G>C p.W1422C | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV99868212; called by muse, mutect2
- COL3A1 | c.1337G>C p.R446P | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as rs149852181; called by muse, mutect2, varscan2
- COL7A1 | c.4482+1G>A p.X1494_splice | Splice Site (SNP) | VAF 16/95 reads (17%) | catalogued as CS072162, COSV100097784; called by muse, mutect2, varscan2
- COPS7A | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 18/123 reads (15%) | catalogued as COSV99976592; called by muse, mutect2, varscan2
- CPZ | c.1325G>T p.S442I (on ENST00000360986 / NM_001014447.3; = p.S431I on NM_003652.3) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100249303; called by muse, mutect2
- CRACD | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1248725099, COSV51715056, COSV99949757; called by muse, mutect2, varscan2
- CRB1 | c.4191G>T p.M1397I | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100959503; called by muse, mutect2, varscan2
- CRLF2 | c.552G>T p.W184C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101053848; called by muse, mutect2, varscan2
- CRLF3 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.006); catalogued as COSV100158551, COSV60837000; called by mutect2, varscan2
- CSMD1 | c.10212C>G p.Y3404* (on ENST00000520002; = p.Y3403* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 4/53 reads (8%) | catalogued as COSV100154057, COSV59352704; called by muse, mutect2
- CSTL1 | c.430C>A p.L144I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV99851227; called by muse, mutect2
- CWF19L2 | c.2167A>T p.T723S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV56513780; called by muse, mutect2, varscan2
- DCC | c.3517C>A p.P1173T | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as COSV71440154; called by muse, mutect2, varscan2
- DCDC1 | c.2520G>T p.E840D | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.075); catalogued as COSV100664223; called by muse, mutect2
- DCX | c.980C>G p.P327R (on ENST00000636035 / NM_001195553.2; = p.P322R on NM_000555.3) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs1453286620, COSV100576775; called by muse, mutect2, varscan2
- DDX53 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as rs1220459956, COSV100029110; called by muse, mutect2, varscan2
- DELE1 | c.1317del p.S441Afs*3 | Frame Shift Del (DEL) | VAF 13/102 reads (13%) | catalogued as rs1561524521, COSV52003752; called by mutect2, pindel, varscan2
- DEPDC5 | c.742G>T p.G248W | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763609844, COSV99836645; called by muse, mutect2, varscan2
- DGKQ | c.2085G>C p.E695D | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV99298254; called by muse, mutect2, varscan2
- DISC1 | c.384G>T p.L128F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV54422868; called by muse, mutect2, varscan2
- DISC1 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.11); catalogued as COSV99697779, COSV99698700; called by muse, mutect2, varscan2
- DISC1 | c.1277G>T p.G426V | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as COSV99697202, COSV99698708; called by muse, mutect2, varscan2
- DNAH2 | c.6662G>T p.R2221L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771773961, COSV101209612; called by muse, mutect2, varscan2
- DNAH7 | c.1076C>G p.S359C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs1023693739, COSV100417731; called by muse, mutect2
- DROSHA | c.1247C>G p.T416S | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV100757829; called by muse, mutect2
- DSG1 | c.1565C>G p.T522S | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs772134381, COSV99936605; called by muse, mutect2, varscan2
- DUOX2 | c.2329del p.A777Lfs*26 | Frame Shift Del (DEL) | VAF 14/87 reads (16%) | catalogued as COSV66532895; called by mutect2, pindel, varscan2
- DYNAP | c.233G>T p.G78V (on ENST00000321600; = p.G52V on NM_173629.3) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV100391909; called by muse, mutect2, varscan2
- ECE1 | c.602A>T p.E201V | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.182); catalogued as rs751269183, COSV99942177, COSV99942361; called by muse, mutect2
- EME2 | c.691A>G p.N231D | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV99457459; called by muse, mutect2
- ENPP1 | c.736A>G p.K246E | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as rs774807507, COSV100719662; called by muse, mutect2
- ENTPD6 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 18/259 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV100737188; called by muse, mutect2
- EPHA10 | c.568C>A p.L190M | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57625606; called by muse, varscan2
- EPHA2 | c.2026A>G p.I676V | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV100626311; called by muse, mutect2, varscan2
- EPPK1 | c.6085A>G p.T2029A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1466875843, COSV101599961; called by muse, mutect2, varscan2
- EYA4 | c.34G>T p.V12L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV100766392; called by muse, mutect2, varscan2
- F11 | c.1591A>T p.T531S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs747777627, COSV99250938; called by mutect2, varscan2
- F5 | c.3686T>A p.M1229K | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV100889259, COSV63128586; called by muse, mutect2
- FAM135B | c.3901G>T p.G1301W | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99420222, COSV99428007; called by muse, mutect2
- FAM167B | c.197G>C p.G66A | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100406014, COSV61110453; called by muse, mutect2, varscan2
- FAM209A | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV99711740; called by muse, mutect2
- FAM234A | c.579G>T p.G193= | Splice Region (SNP) | VAF 14/78 reads (18%) | catalogued as COSV100056552; called by muse, mutect2, varscan2
- FAM83D | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.033); catalogued as COSV99465523; called by muse, mutect2, varscan2
- FHL5 | c.159+2T>C p.X53_splice | Splice Site (SNP) | VAF 3/42 reads (7%) | catalogued as COSV100459823; called by muse, mutect2
- FLG2 | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 15/241 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.434); catalogued as COSV101166245; called by muse, mutect2
- FLT4 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.213); catalogued as rs867280522, COSV56116045, COSV99989155; called by muse, mutect2, varscan2
- FNDC7 | c.1609G>C p.V537L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV99601768; called by muse, mutect2
- GABRB1 | c.686C>A p.A229E | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.41); catalogued as COSV99783619; called by muse, mutect2
- GBP5 | c.1294A>T p.N432Y | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV100600173; called by muse, mutect2
- GIMAP6 | c.600C>A p.N200K | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100188408; called by muse, mutect2
- GLRA3 | c.801T>G p.I267M | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99928243; called by muse, mutect2, varscan2
- GNL3L | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100328625; called by muse, mutect2, varscan2
- GNPAT | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as COSV100791719; called by muse, mutect2, varscan2
- GPD2 | c.1844G>C p.R615P | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as COSV100133683, COSV60090311; called by muse, mutect2, varscan2
- GPR101 | c.787C>A p.R263S | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.03); catalogued as COSV104402171, COSV99981639; called by muse, mutect2, varscan2
- GPR137 | c.1114G>A p.G372S | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV100464536; called by muse, mutect2, varscan2
- GPR162 | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.073); catalogued as COSV50593497, COSV99163920; called by muse, mutect2
- GPR173 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as rs945694480, COSV100212193, COSV100212248, COSV100212429; called by muse, varscan2
- GRAMD1A | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs746163845, COSV100526429; called by muse, mutect2, varscan2
- GRID1 | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.999); catalogued as rs770160415, COSV60012059, COSV60039732; called by mutect2, varscan2
- GRIK3 | c.2327G>T p.R776L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100902376; called by muse, mutect2, varscan2
- HCN2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.018); catalogued as rs1262524303, COSV52113828; called by muse, mutect2, varscan2
- HEPACAM2 | c.947G>A p.C316Y (on ENST00000394468 / NM_001039372.4; = p.C304Y on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as COSV100506811; called by muse, mutect2, varscan2
- HEPH | c.3243A>T p.K1081N (on ENST00000343002; = p.K814N on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as COSV100295794; called by muse, mutect2, varscan2
- HOOK2 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs200402327; called by muse, mutect2
- HOXD12 | c.813G>T p.*271Yext*26 | Nonstop Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as rs750205896, COSV101184358; called by muse, mutect2, varscan2
- HSD3B1 | c.517A>T p.N173Y | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99348112; called by muse, mutect2, varscan2
- HTR1E | c.489C>G p.H163Q | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV100541328, COSV59507405, COSV59508158; called by muse, mutect2, varscan2
- IFT80 | c.38A>T p.H13L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV100425149; called by muse, mutect2, varscan2
- IGKJ5 | c.22A>G p.T8A | Missense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as rs558546033; called by mutect2, varscan2
- IL31 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100986594; called by muse, mutect2, varscan2
- IL36RN | c.164C>G p.S55C | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100697301, COSV61010445; called by muse, mutect2
- INSRR | c.3460C>A p.L1154M | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63871401; called by muse, mutect2
- IPMK | c.308T>G p.L103R | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100880478; called by muse, mutect2
- IRAG2 | c.4178A>T p.N1393I (on ENST00000636465; = p.N438I on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100209770; called by muse, mutect2
- IRS4 | c.419C>A p.P140Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs778423131, COSV100929746; called by muse, mutect2, varscan2
- IST1 | c.245T>C p.M82T (on ENST00000535424 / NM_001270976.1; = p.M69T on NM_014761.4) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100324894; called by muse, mutect2, varscan2
- ITGA1 | c.2168G>T p.R723L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.176); catalogued as COSV50879030, COSV99252218; called by muse, mutect2
- ITGAD | c.1774G>T p.D592Y | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101210592, COSV66759634; called by muse, mutect2, varscan2
- ITIH2 | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs968030730, COSV64433936; called by muse, mutect2
- ITIH5 | c.2354G>T p.G785V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.981); catalogued as COSV99905842; called by muse, mutect2, varscan2
- KAT6A | c.2812A>G p.R938G | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1174145893, COSV99705931; called by muse, mutect2
- KCNA4 | c.1240C>A p.P414T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100069294; called by muse, mutect2, varscan2
- KIF2B | c.1447C>A p.L483M | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV52129785, COSV99276340; called by muse, mutect2
- KIF2B | c.1567G>C p.G523R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1382355019, COSV52134563, COSV99276341; called by muse, mutect2, varscan2
- KLHL42 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.734); catalogued as COSV101179867; called by muse, mutect2, varscan2
- KMT2A | c.8518G>T p.D2840Y | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100629959, COSV63289708; called by muse, mutect2
- KMT2C | c.4822G>T p.A1608S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV100076865; called by muse, mutect2, varscan2
- KMT2E | c.2948G>T p.R983I | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99996574; called by muse, mutect2
- KRT2 | c.1390C>T p.Q464* | Nonsense Mutation (SNP) | VAF 9/129 reads (7%) | catalogued as COSV100548364, COSV100548670; called by muse, mutect2
- KRT26 | c.1039G>T p.D347Y | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV59412740; called by muse, mutect2, varscan2
- KRT26 | c.1038G>T p.Q346H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100156622; called by muse, mutect2, varscan2
- KSR2 | c.2273T>C p.L758S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100196787; called by muse, mutect2, varscan2
- LAMA1 | c.7102G>T p.D2368Y | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101057836; called by muse, mutect2, varscan2
- LAMA5 | c.8884A>T p.T2962S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1248080190, COSV99442481; called by muse, mutect2
- LIG4 | c.347C>G p.T116S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1451327869, COSV100800078; called by muse, mutect2, varscan2
- LMBR1 | c.795G>T p.L265F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV100626879; called by muse, mutect2, varscan2
- LMX1A | c.579G>T p.K193N | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV99673259; called by muse, mutect2
- LRFN5 | c.880C>G p.H294D | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as COSV99985566; called by muse, mutect2, varscan2
- LRP1B | c.11267C>A p.T3756K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV101261452; called by muse, mutect2, varscan2
- LRRTM2 | c.1389C>G p.N463K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV99217891; called by muse, mutect2, varscan2
- LYST | c.4427C>T p.S1476F | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV67715228; called by muse, mutect2
- MACF1 | c.15357G>T p.M5119I (on ENST00000372915; = p.M3052I on NM_012090.5) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99241256, COSV99247025; called by muse, mutect2, varscan2
- MAP3K19 | c.2623A>G p.T875A | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV100209351; called by muse, mutect2, varscan2
- MARS2 | c.1279A>C p.T427P | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99986707; called by muse, mutect2, varscan2
- MASP1 | c.440A>C p.E147A | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.017); catalogued as COSV99397693; called by muse, mutect2, varscan2
- MC4R | c.887T>C p.I296T | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as COSV100236144; called by muse, mutect2
- MCF2 | c.2109G>C p.W703C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100645197; called by muse, mutect2, varscan2
- MCOLN2 | c.1040A>G p.Y347C | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV99394302; called by muse, mutect2, varscan2
- MED4 | c.592G>C p.V198L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.333); catalogued as COSV51638827, COSV99320088; called by muse, mutect2, varscan2
- MEIS3 | c.665G>T p.S222I | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs1421500611, COSV100520562; called by muse, mutect2
- MFSD4A | c.318G>T p.K106N | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.073); catalogued as COSV100901726; called by muse, mutect2
- MOCS2 | c.473T>C p.L158S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100799074; called by mutect2, varscan2
- MRC1 | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs1334393236; called by muse, mutect2, varscan2
- MS4A6E | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV100279236; called by muse, mutect2, varscan2
- MUC16 | c.20388A>G p.I6796M | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.183); catalogued as COSV101201831; called by muse, mutect2, varscan2
- MUC17 | c.4570A>T p.T1524S | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.739); catalogued as COSV100075147; called by muse, mutect2, varscan2
- MUC17 | c.10193C>G p.T3398S | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs762182801, COSV100075148; called by muse, mutect2
- MUC3A | c.8395C>A p.P2799T | Missense Mutation (SNP) | VAF 29/295 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as COSV100114286, COSV100115128; called by muse, mutect2
- MUC3A | c.8396C>T p.P2799L | Missense Mutation (SNP) | VAF 29/298 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV100114288; called by muse, mutect2
- MYH7 | c.1645A>G p.K549E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV100806707; called by muse, mutect2, varscan2
- MYH8 | c.2854G>T p.E952* | Nonsense Mutation (SNP) | VAF 9/171 reads (5%) | catalogued as COSV101238852; called by muse, mutect2
- NAA60 | c.491A>G p.Y164C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV100692863; called by muse, mutect2, varscan2
- NAV2 | c.6296C>G p.P2099R (on ENST00000396087 / NM_001244963.2; = p.P2040R on NM_145117.5) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100217678; called by muse, mutect2, varscan2
- NAV3 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs370324426, COSV57065714, COSV99886565; called by muse, mutect2
- NEO1 | c.3284G>T p.S1095I | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs1227245517, COSV99982839; called by muse, mutect2
- NID2 | c.1691G>T p.R564I | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99357327; called by muse, mutect2, varscan2
- NKD2 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.117); catalogued as COSV99724441; called by muse, mutect2
- NMNAT2 | c.553G>T p.V185L | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.067); catalogued as rs1329963956, COSV99680416; called by muse, mutect2, varscan2
- NOTCH4 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV66679287, COSV66682818; called by muse, mutect2
- NPC1L1 | c.2166+1del p.X722_splice | Splice Site (DEL) | VAF 19/116 reads (16%) | catalogued as COSV56923987; called by mutect2, pindel, varscan2
- NRK | c.502C>A p.L168I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99689229; called by muse, mutect2, varscan2
- NSMCE3 | c.646T>C p.F216L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV99723653; called by muse, mutect2, varscan2
- NTRK1 | c.1378G>T p.D460Y | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100693812; called by muse, mutect2, varscan2
- NTRK1 | c.2357A>T p.Q786L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV100693813; called by muse, mutect2
- OPHN1 | c.1172G>T p.R391M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100830798; called by muse, mutect2
- OR10P1 | c.467C>A p.T156K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100548218; called by muse, mutect2, varscan2
- OR2A5 | c.629C>A p.P210Q | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370562017, COSV101278863, COSV68738930; called by muse, mutect2, varscan2
- OR2F2 | c.746C>A p.A249D | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.309); catalogued as COSV101283860; called by muse, mutect2
- OR2L13 | c.662T>A p.L221Q | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100813896; called by muse, mutect2
- OR2T10 | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100393823; called by muse, mutect2, varscan2
- OR2T27 | c.913G>T p.V305L | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61282079; called by muse, mutect2, varscan2
- OR2Y1 | c.841A>T p.T281S | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV100322864; called by muse, mutect2, varscan2
- OR4D5 | c.569C>A p.T190K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100190196; called by muse, mutect2, varscan2
- OR4K5 | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV100262639; called by muse, mutect2
- OR56A1 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100360565; called by muse, mutect2, varscan2
- OR5D16 | c.806C>A p.S269Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101004152; called by muse, mutect2, varscan2
- OR6B3 | c.695C>A p.T232N | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as COSV100097693; called by muse, mutect2
- OR6T1 | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100190197; called by muse, mutect2
- OR8H2 | c.746C>G p.T249S | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.718); catalogued as COSV100542490; called by muse, mutect2
- OR9K2 | c.796T>G p.C266G (on ENST00000305377; = p.C244G on NM_001005243.1) | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100543937; called by muse, mutect2
- PAGE5 | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.813); catalogued as COSV56943618, COSV99215864; called by muse, mutect2, varscan2
- PALB2 | c.2701C>A p.L901M | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV99849020; called by muse, mutect2, varscan2
- PARVA | c.303A>C p.L101F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100616875; called by muse, mutect2, varscan2
- PCDHA6 | c.1970C>A p.P657Q | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100971857, COSV65343541; called by muse, mutect2, varscan2
- PCDHGB5 | c.1699G>T p.G567C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV99540939; called by muse, mutect2, varscan2
- PCSK5 | c.922G>T p.V308F | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100950732; called by muse, mutect2, varscan2
- PCSK5 | c.4229A>G p.Y1410C | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV101377719; called by muse, mutect2
- PDE3A | c.2506C>A p.H836N | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100762832; called by muse, mutect2
- PDGFRA | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1060501502, COSV57267051, COSV57268494; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGK2 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100505719; called by muse, mutect2
- PGLYRP3 | c.81G>T p.K27N | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV99319970; called by muse, mutect2
- PIK3CG | c.1054G>T p.V352L | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV100783219, COSV63249288; called by muse, mutect2, varscan2
- PKHD1 | c.3886G>T p.E1296* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100584674; called by muse, mutect2, varscan2
- PLCB1 | c.2948C>A p.P983H | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.359); catalogued as COSV100572252; called by muse, mutect2, varscan2
- PLCXD1 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.089); catalogued as rs377656781, COSV101088012; called by muse, mutect2
- PLEKHA5 | c.3110G>T p.S1037I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100164786; called by muse, mutect2
- PLEKHA6 | c.1625A>T p.K542M | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99692823; called by muse, mutect2
- PLRG1 | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100123270; called by muse, mutect2, varscan2
- PPP1R13L | c.755A>T p.E252V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV62908394; called by muse, mutect2, varscan2
- PRB1 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 66/474 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); catalogued as rs774051539, COSV53703840, COSV53706948, COSV53707158; called by muse, mutect2, varscan2
- PRDM14 | c.969C>A p.N323K | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99400545; called by muse, mutect2
- PRLR | c.749T>A p.L250* | Nonsense Mutation (SNP) | VAF 7/93 reads (8%) | catalogued as COSV99184803; called by muse, mutect2
- PRPF8 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775023296, COSV59264465; ClinVar: uncertain significance; called by muse, mutect2
- PRSS57 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV100249702; called by muse, mutect2, varscan2
- PTBP3 | c.1257A>T p.R419S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV100534568; called by muse, mutect2, varscan2
- PTH2R | c.457T>C p.S153P | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99782934; called by muse, mutect2, varscan2
- PTPRU | c.3440G>T p.C1147F | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); catalogued as COSV100113793, COSV60535940; called by muse, mutect2
- PXDN | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.17); catalogued as COSV99415007; called by muse, mutect2
- RANBP2 | c.1632-1G>C p.X544_splice | Splice Site (SNP) | VAF 10/79 reads (13%) | catalogued as COSV99313398; called by muse, mutect2, varscan2
- RAPH1 | c.1697A>T p.H566L (on ENST00000319170 / NM_213589.3; = p.H618L on NM_203365.4) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV99864562; called by muse, mutect2
- RASGEF1A | c.1186C>A p.H396N | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV100988641, COSV100988733; called by muse, mutect2, varscan2
- RASGRP4 | c.1605G>T p.L535F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99385166; called by muse, mutect2, varscan2
- RDH8 | c.259G>A p.V87M (on ENST00000651512; = p.V67M on NM_015725.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs545999307, COSV50674739; called by muse, mutect2, varscan2
- RET | c.2802A>T p.V934= | Splice Region (SNP) | VAF 11/182 reads (6%) | catalogued as COSV100394691; called by muse, mutect2
- RETREG2 | c.458G>T p.S153I | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56088490, COSV56088952; called by muse, mutect2
- RIMS1 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1411730533, COSV53449107, COSV99330722; called by muse, mutect2, varscan2
- RPL3L | c.431A>T p.K144M | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99238506; called by muse, mutect2, varscan2
- RYR3 | c.9879G>A p.M3293I (on ENST00000389232; = p.M3294I on NM_001036.6) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.709); catalogued as COSV101214717; called by muse, mutect2, varscan2
- SCN3A | c.3278T>C p.F1093S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV99328623; called by muse, mutect2, varscan2
- SELP | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as COSV99741218; called by muse, mutect2, varscan2
- SEPTIN2 | c.735G>C p.L245F | Missense Mutation (SNP) | VAF 20/291 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100764992, COSV63632753; called by muse, mutect2
- SERPINA1 | c.116A>T p.H39L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100872197; called by muse, mutect2, varscan2
- SHROOM4 | c.2191G>C p.E731Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99174767; called by muse, mutect2, varscan2
- SLC12A6 | c.3228G>T p.P1076= (on ENST00000354181 / NM_001365088.1; = p.P1025= on NM_005135.2) | Splice Region (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99273482; called by muse, mutect2, varscan2
- SLC39A3 | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as COSV99514322; called by muse, mutect2, varscan2
- SPATA31D1 | c.2143C>A p.P715T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100783075; called by muse, mutect2, varscan2
- SPATA31D1 | c.2144C>A p.P715H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100783076; called by muse, mutect2, varscan2
- SPATA4 | c.696T>A p.F232L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99709120; called by muse, mutect2, varscan2
- SPATC1 | c.1135C>G p.P379A | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.058); catalogued as COSV101085350; called by muse, mutect2
- SRPK2 | c.1877G>T p.R626L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100624364, COSV104421872; called by muse, mutect2
- ST8SIA2 | c.771G>C p.E257D | Missense Mutation (SNP) | VAF 16/83 reads (19%) | PolyPhen benign (0.013); catalogued as COSV99184539; called by muse, mutect2, varscan2
- STAB2 | c.686G>C p.R229P | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV101186364, COSV66339439; called by muse, mutect2, varscan2
- STAB2 | c.3129C>G p.D1043E | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV101186367; called by muse, mutect2
- STAB2 | c.4783T>C p.C1595R | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101186369; called by muse, mutect2
- STK36 | c.2854A>T p.M952L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.109); catalogued as COSV99831980; called by muse, mutect2
- STYXL2 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99609932; called by muse, mutect2, varscan2
- SYNE2 | c.14590G>T p.V4864L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV100648532; called by muse, mutect2, varscan2
- SZT2 | c.5421G>T p.R1807S (on ENST00000634258 / NM_001365999.1; = p.R1750S on NM_015284.4) | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV65167503; called by muse, mutect2
- TBC1D5 | c.77G>T p.S26I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99511999; called by muse, mutect2, varscan2
- TBX5 | c.1050A>T p.E350D | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100092255; called by muse, mutect2
- TCEAL5 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101013192; called by muse, mutect2, varscan2
- TFEC | c.417A>T p.Q139H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99625290; called by muse, mutect2, varscan2
- TJP2 | c.900G>T p.R300S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.13); catalogued as COSV99601886; called by mutect2, varscan2
- TKTL2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99761773; called by muse, mutect2
- TMEM154 | c.304A>T p.K102* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100433218; called by muse, mutect2, varscan2
- TMEM52B | c.382C>A p.L128M (on ENST00000381923 / NM_001079815.1; = p.L108M on NM_153022.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.735); catalogued as COSV100046538; called by muse, mutect2, varscan2
- TNNT2 | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99372186; called by muse, mutect2, varscan2
- TNR | c.3977G>A p.W1326* | Nonsense Mutation (SNP) | VAF 7/74 reads (9%) | catalogued as COSV99691753; called by muse, mutect2
- TP53I13 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV99838448; called by muse, mutect2
- TRIM41 | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV100163536; called by muse, mutect2, varscan2
- TRPM6 | c.3350G>A p.R1117H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.63); catalogued as rs772621095, COSV100667016; called by muse, mutect2, varscan2
- TSHZ1 | c.2660G>T p.G887V (on ENST00000580243 / NM_001308210.2; = p.G842V on NM_005786.6) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100433949; called by muse, mutect2, varscan2
- TTN | c.66653T>C p.L22218S (on ENST00000591111; = p.L14794S on NM_003319.4) | Missense Mutation (SNP) | VAF 10/103 reads (10%) | PolyPhen probably damaging (0.999); catalogued as COSV100631437; called by muse, mutect2
- TTN | c.44236G>T p.V14746F (on ENST00000591111; = p.V7322F on NM_003319.4) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | PolyPhen benign (0.238); catalogued as COSV100631445; called by muse, mutect2, varscan2
- TTYH1 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs1402227266, COSV100002451; called by muse, mutect2
- UNC5C | c.2147A>T p.H716L | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV101498048; called by muse, mutect2
- UNC5C | c.2146C>T p.H716Y | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV71660537; called by muse, mutect2
- UPB1 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV100387320; called by muse, mutect2
- USP21 | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99237831; called by muse, mutect2
- VCAN | c.7662A>T p.L2554F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV99427431; called by muse, mutect2, varscan2
- VWA8 | c.5699C>T p.T1900I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101023006; called by muse, mutect2, varscan2
- YY1AP1 | c.1240G>C p.E414Q (on ENST00000295566 / NM_139118.2; = p.E357Q on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.888); catalogued as COSV99804750; called by muse, mutect2
- ZC3H18 | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV99964453; called by muse, mutect2, varscan2
- ZFHX4 | c.7625C>A p.P2542H | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50893025, COSV99268102; called by muse, mutect2
- ZFPM2 | c.224C>G p.T75R | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as COSV101343563; called by muse, mutect2
- ZNF461 | c.588G>T p.K196N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100831494; called by muse, mutect2, varscan2
- ZNF607 | c.712G>T p.G238* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100777964; called by muse, mutect2, varscan2
- ZNF652 | c.1270A>G p.M424V | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100755694; called by muse, mutect2, varscan2
- ZNF655 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV99402382; called by muse, mutect2
- ZNF709 | c.1297A>T p.S433C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV101172319; called by muse, varscan2
- ZNF804B | c.2507G>C p.C836S | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.113); catalogued as COSV100306399, COSV60821904; called by muse, mutect2
- ZNF831 | c.1870G>T p.G624W | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100926281, COSV64039296; called by muse, mutect2
- ZP4 | c.177delinsAA p.D59Efs*12 | Frame Shift Ins (INS) | VAF 8/51 reads (16%) | catalogued as COSV63913738; called by pindel, varscan2*
- ZXDA | c.1784A>T p.Q595L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV100699473; called by muse, mutect2, varscan2
- APBB1IP | c.1286G>C p.R429P | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.206); called by muse, mutect2
- DMBT1 | c.1623G>A p.M541I | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCGBP | c.8953G>T p.V2985L | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.04); called by muse, mutect2
- GABRQ | c.148T>A p.C50S | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- IGHA1 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.86); called by muse, mutect2
- IGHV1OR15-9 | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- KIAA0930 | c.753G>T p.K251N (on ENST00000336156 / NM_001009880.2; = p.K256N on NM_015264.2) | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- L3MBTL3 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MROH1 | c.2005C>G p.L669V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- OR14I1 | c.361T>C p.Y121H | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2
- P3H2 | c.2087_2091del p.G696Afs*2 | Frame Shift Del (DEL) | VAF 3/38 reads (8%) | called by mutect2, pindel
- PTGFRN | c.2060-1G>T p.X687_splice | Splice Site (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- RASAL1 | c.1052dup p.M351Ifs*22 | Frame Shift Ins (INS) | VAF 29/183 reads (16%) | called by mutect2, pindel, varscan2
- SIN3A | c.3307G>T p.E1103* | Nonsense Mutation (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- SPTB | c.5380del p.A1794Pfs*106 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | called by mutect2, pindel, varscan2
- USH2A | c.2326C>A p.Q776K | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2
- ADRA2B | c.456C>T p.G152= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV69788183; called by muse, mutect2, varscan2
- ANK2 | c.4215C>A p.A1405= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100004347; called by muse, mutect2, varscan2
- ANK2 | c.11115C>A p.T3705= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100004350; called by muse, mutect2, varscan2
- APBB1IP | c.1287G>T p.R429= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV100882269; called by muse, mutect2
- BARHL2 | c.141C>A p.A47= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as COSV100966111, COSV64982162; called by muse, mutect2
- CD1E | c.492G>T p.R164= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100937072; called by muse, mutect2, varscan2
- CELA2B | c.435C>A p.A145= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV101025885; called by muse, mutect2, varscan2
- COL2A1 | c.1065T>C p.P355= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as COSV100477577; called by muse, mutect2
- DSE | c.1617A>G p.G539= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100528807; called by muse, mutect2, varscan2
- EFEMP2 | c.966C>G p.V322= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1266555258, COSV100337402; called by muse, mutect2, varscan2
- EFHC2 | c.462C>T p.V154= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs749456044, COSV69553258; called by muse, mutect2, varscan2
- ELAPOR2 | c.2835G>T p.L945= (on ENST00000450689 / NM_001142749.3; = p.L778= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV99789425; called by muse, mutect2
- EPRS1 | c.2496A>C p.A832= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100859520; called by muse, mutect2
- FAM166A | c.117G>C p.T39= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs368787356, COSV100458240, COSV61116926, COSV61117381; called by muse, mutect2, varscan2
- FAM81A | c.267A>C p.I89= | Silent (SNP) | VAF 16/164 reads (10%) | catalogued as COSV99893633; called by muse, mutect2
- FOXN4 | c.1044C>A p.P348= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100142342; called by muse, varscan2
- GABRA1 | c.1239T>C p.F413= | Silent (SNP) | VAF 8/99 reads (8%) | catalogued as COSV99196297; called by muse, mutect2
- GALE | c.900G>T p.R300= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV100994856; called by muse, mutect2, varscan2
- GPR26 | c.807G>T p.V269= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV99501132; called by muse, mutect2, varscan2
- HHATL | c.624C>G p.L208= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as rs1470331169, COSV100124667; called by muse, mutect2, varscan2
- HOXB1 | c.96C>A p.P32= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV99495687; called by muse, mutect2, varscan2
- IL7R | c.1170C>T p.C390= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV100286701, COSV57412269; called by muse, mutect2, varscan2
- IWS1 | c.858C>T p.A286= | Silent (SNP) | VAF 38/188 reads (20%) | catalogued as COSV99767538; called by muse, mutect2, varscan2
- JAKMIP2 | c.424C>A p.R142= | Silent (SNP) | VAF 11/147 reads (7%) | catalogued as COSV99509321; called by muse, mutect2
- KCND3 | c.1833C>A p.T611= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100138501; called by muse, mutect2, varscan2
- KIF1C | c.1089T>A p.I363= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as COSV100297310; called by muse, mutect2
- KMO | c.816C>G p.L272= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100844724; called by muse, mutect2, varscan2
- KRTAP10-10 | c.195C>A p.G65= | Silent (SNP) | VAF 16/151 reads (11%) | catalogued as COSV100555581; called by muse, mutect2, varscan2
- KRTAP9-4 | c.303C>T p.C101= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as COSV100484975; called by muse, mutect2, varscan2
- L3MBTL4 | c.738A>G p.P246= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV53119609; called by muse, mutect2, varscan2
- LAMB4 | c.3465C>A p.G1155= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV99225737; called by muse, mutect2, varscan2
- LRCH4 | c.831C>T p.P277= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV100053198; called by muse, mutect2, varscan2
- MAP4K1 | c.40C>A p.R14= | Silent (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- MFGE8 | c.570G>T p.A190= | Silent (SNP) | VAF 12/155 reads (8%) | catalogued as COSV51556239; called by muse, mutect2
- MINAR1 | c.1797G>T p.L599= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as COSV100549312; called by muse, mutect2, varscan2
- MUC17 | c.10194C>A p.T3398= | Silent (SNP) | VAF 18/301 reads (6%) | catalogued as COSV100075149; called by muse, mutect2
- MUC6 | c.2067C>T p.T689= | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as rs1437643781, COSV70151965; called by muse, mutect2, varscan2
- MYF6 | c.448C>A p.R150= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV99952962; called by muse, mutect2
- MYH8 | c.3387G>A p.R1129= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs1326683243, COSV101238850; called by muse, mutect2, varscan2
- NMUR1 | c.1092A>G p.R364= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV100532173; called by muse, mutect2, varscan2
- NUP153 | c.2100A>C p.P700= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV100020858, COSV50469674; called by muse, mutect2
- NXPH4 | c.600G>C p.A200= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100197417; called by mutect2, varscan2
- OR13F1 | c.492G>T p.L164= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100594865; called by muse, mutect2
- OR51E1 | c.351G>T p.V117= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV101211563; called by muse, mutect2
- OR52I2 | c.594C>T p.F198= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as COSV100443022; called by muse, mutect2
- OR5D16 | c.171G>A p.L57= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV101004151; called by muse, mutect2, varscan2
- OR6A2 | c.510C>A p.G170= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as rs748995268, COSV100215829; called by muse, mutect2, varscan2
- OSBPL6 | c.1167G>A p.L389= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV99508581; called by muse, mutect2
- P2RY1 | c.30C>T p.P10= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs1274408154, COSV100521806; called by mutect2, varscan2
- PIK3CG | c.759C>A p.A253= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV100783218; called by muse, mutect2
- PLXNA4 | c.4752G>T p.L1584= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as rs1316215544, COSV100327306, COSV58158483; called by muse, mutect2
- PRAMEF15 | c.1242G>T p.L414= | Silent (SNP) | VAF 13/242 reads (5%) | called by muse, mutect2
- RABL3 | c.552G>T p.R184= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV99846662; called by muse, mutect2, varscan2
- RCVRN | c.186C>G p.P62= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs768115965, COSV99874384; called by muse, mutect2
- RNFT2 | c.408G>T p.G136= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99985599; called by muse, varscan2
- ROBO2 | c.3222A>C p.L1074= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100170164; called by muse, mutect2, varscan2
- RYR3 | c.5934G>T p.L1978= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV66793485; called by muse, mutect2, varscan2
- SCN1A | c.2832G>T p.V944= (on ENST00000303395 / NM_001202435.3; = p.V933= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/184 reads (23%) | catalogued as COSV100322271; called by muse, mutect2, varscan2
- SEPTIN4 | c.753T>A p.G251= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100400454; called by muse, mutect2, varscan2
- SIDT1 | c.768G>A p.E256= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99334778; called by muse, mutect2, varscan2
- SLC1A6 | c.294G>A p.R98= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs1195708531, COSV99694233; called by muse, mutect2, varscan2
- SOWAHB | c.1026C>A p.P342= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100530800; called by muse, mutect2
- SPATA31E1 | c.2538C>T p.H846= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100351107; called by muse, mutect2, varscan2
- SRGAP1 | c.720G>T p.R240= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100755170, COSV61895605; called by muse, mutect2
- TAL1 | c.858C>A p.S286= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV99595975; called by muse, mutect2, varscan2
- TESPA1 | c.1380C>G p.T460= (on ENST00000316577 / NM_001098815.3; = p.T322= on NM_014796.2 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as COSV100345359; called by muse, mutect2, varscan2
- TRIM10 | c.372T>C p.A124= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV100938868; called by muse, mutect2, varscan2
- TRPM3 | c.1338A>G p.T446= (on ENST00000357533 / NM_001366142.2; = p.T291= on NM_020952.6) | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100678815; called by muse, mutect2, varscan2
- TTN | c.91875C>T p.S30625= (on ENST00000591111; = p.S23201= on NM_003319.4) | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as rs1456437728, COSV100631435; called by muse, mutect2
- TTN | c.65712T>G p.T21904= (on ENST00000591111; = p.T14480= on NM_003319.4) | Silent (SNP) | VAF 13/186 reads (7%) | catalogued as COSV100631438; called by muse, mutect2
- TTN | c.55488C>A p.T18496= (on ENST00000591111; = p.T11072= on NM_003319.4) | Silent (SNP) | VAF 38/250 reads (15%) | catalogued as COSV100631442; called by muse, mutect2, varscan2
- UBE2O | c.1083A>G p.V361= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as rs767922110, COSV100085082; called by muse, mutect2, varscan2
- UNC13C | c.6510T>G p.P2170= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99523276; called by muse, mutect2
- USP5 | c.1989G>A p.L663= (on ENST00000229268 / NM_001098536.2; = p.L640= on NM_003481.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as COSV99979081; called by muse, mutect2, varscan2
- WWC1 | c.1524G>A p.K508= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV99515997; called by muse, mutect2, varscan2
- XIRP1 | c.3951C>A p.T1317= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV100453990; called by muse, mutect2, varscan2
- ZFP64 | c.1764C>T p.P588= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs868792368, COSV99403073; called by muse, mutect2, varscan2
- ZIC3 | c.792C>A p.P264= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99799561; called by muse, mutect2, varscan2
- ZNF654 | c.2469C>T p.N823= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs746078281, COSV58805470, COSV58806203; called by muse, mutect2, varscan2
- ZNF658 | c.2970G>T p.G990= | Silent (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2, varscan2
- AL136982.4 | n.1441G>T | RNA (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821065 C>A | 3'Flank (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- KRT18P55 | n.592C>T | RNA (SNP) | VAF 20/76 reads (26%) | catalogued as rs746101736; called by muse, mutect2, varscan2
- LY9 | c.454+1800C>A | Intron (SNP) | VAF 19/145 reads (13%) | catalogued as COSV99627504; called by muse, mutect2, varscan2
- MIR506 | n.2C>A | RNA (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- OBSCN | c.11660-1882C>A | Intron (SNP) | VAF 20/123 reads (16%) | catalogued as rs759152279, COSV99484625; called by muse, mutect2, varscan2
- SNORD116-5 | n.48C>A | RNA (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- STT3A | c.-1G>A | 5'UTR (SNP) | VAF 6/46 reads (13%) | catalogued as COSV101205294; called by muse, mutect2
